Gene-level copy-number profile of tumor specimen TCGA-KU-A66S-01A from TCGA case TCGA-KU-A66S, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.7 years (25,454 days).
Specimen TCGA-KU-A66S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6086fce5-5225-4e01-8b27-e32cbb33d52e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KU-A66S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96c8917e-be6f-47d8-abdd-78a0fe27e9cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 745; copy number 2: 55,499; copy number 3: 376; copy number 4: 2,481; copy number 5: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KU-A66S-01A-21D-A30D-01): tumor purity 0.78, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,892,792–15,118,043, 6 genes (within-gene range 0–2): KAZN, RNU6-1265P, AL357873.1, KAZN-AS1, TBCAP2, AL031293.1.
- chr7:92,701,708–92,701,814, 1 gene: RNU6-10P.
- chr7:154,544,169–154,547,285, 1 gene: AC024730.1.
- chr16:7,126,293–7,126,639, 1 gene: AC022206.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 710 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 745. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
